Gene-level copy-number profile of tumor specimen TCGA-HC-7232-01A from TCGA case TCGA-HC-7232, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.6 years (24,324 days).
Specimen TCGA-HC-7232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.579d62a4-c425-40cd-9f4c-28f79639e92d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7232-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b474458-7458-4f3f-90f4-fd24d649c49a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 7,278; copy number 2: 49,444; copy number 3: 3,067.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7232-01A-11D-2112-01): tumor purity 0.6, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:113,797,874–114,414,203, 13 genes (within-gene range 0–1): USP28, AP003170.3, AP003170.1, RNU6-1107P, HTR3B, HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7.
- chr16:72,665,123–73,891,871, 17 genes (within-gene range 0–1): AC004943.2, RNU7-90P, KRT18P18, AC004943.3, ZFHX3, AC004943.1, RNU7-71P, AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1, HCCAT5, AC116667.2, AC140912.1, AC009033.1, LINC01568.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,898. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
